Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6507, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6507-01A (Primary Tumor).

TCGA - EI - 6507

page 1 / 1

Examination: Histopathological examination

Material: Multiple organ resection - segment of the large intestine

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: Tumour located 3 cm from the edge of the rectum, covering the length of 10 cm. Frontal resection.

Examination performed on:

Macroscopic description:

19 cm length of the large intestine with mesorectum fat tissue of 2 cm in thickness. Ulcerous, cauliflower-shaped tumour sized 5.3 x 10 x 4.5 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference and narrows its cross section, located 12.5 cm from the proximal cut end and 4.5 cm from the distal cut end. Minimum side margin is 2 cm.

Microscopic description:

Adenocarcinoma mucinosum (G3).

Infiltratio carcinomatosa tunicae mucularis propriae et tela adiposae meso recti. Incision lines free of neoplastic lesions. Lymphonodulitis reactiva (No XXV).

Examination result/Histopathological diagnosis:

Adenocarcinoma mucinosum recti. **Mucinous adenocarcinoma of the rectum**

(G3, Dukes B, Astler - Coller B2, pT3, pN0, R0).

Source: NCI Genomic Data Commons file 16a5cc87-26f4-4ddf-a9b0-86d26a6477ec (TCGA-EI-6507.88BAD462-FDCF-42BF-9837-5DE3713834B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).